Somatic mutation profile of tumor specimen TCGA-AK-3458-01A (aliquot TCGA-AK-3458-01A-01D-1501-10) from TCGA case TCGA-AK-3458, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 48.1 years (17,557 days).
Specimen TCGA-AK-3458-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d5313bc-f131-4b9c-995e-7b11ef61e310.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3458-10A (Blood Derived Normal), aliquot TCGA-AK-3458-10A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/392c11e0-bf5f-44a6-a54b-b7f1a26c352a

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 3, Intron 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK1 | c.724C>G p.H242D | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV53080322; called by muse, mutect2, varscan2
- AMOT | c.1642C>G p.Q548E (on ENST00000371959 / NM_001113490.1; = p.Q139E on NM_133265.3) | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs774669790, COSV59063031; called by muse, mutect2, varscan2
- BTG4 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 153/543 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV63635656; called by muse, mutect2, varscan2
- BTNL8 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs778289052, COSV51458332, COSV99180501; called by muse, mutect2, varscan2
- CCDC144A | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV60698016; called by muse, mutect2, varscan2
- CYB5R1 | c.605C>G p.P202R | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV65916940; called by muse, mutect2
- DRC1 | c.489C>A p.H163Q | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV56530923; called by muse, mutect2, varscan2
- ELL2 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV52982264; called by muse, mutect2, varscan2
- EPHX1 | c.1150A>G p.T384A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55300397; called by muse, mutect2
- FRMPD2 | c.1490A>T p.D497V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV59717593; called by muse, mutect2, varscan2
- HEATR1 | c.2820G>T p.Q940H | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs766233566, COSV63980936; called by muse, mutect2, varscan2
- HERC2 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55321471; called by muse, mutect2, varscan2
- KDM5C | c.963+2T>C p.X321_splice | Splice Site (SNP) | VAF 81/154 reads (53%) | catalogued as COSV64764616; called by muse, mutect2, varscan2
- PLIN2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52803105; called by muse, mutect2, varscan2
- PLXNA2 | c.4259A>G p.K1420R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.469); catalogued as COSV65440198; called by muse, mutect2, varscan2
- PLXNC1 | c.3702A>C p.K1234N | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51574460; called by muse, mutect2
- PRSS45P | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV70577109; called by muse, mutect2, varscan2
- RALGAPA1 | c.1014A>T p.R338S | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.218); catalogued as COSV99354270; called by muse, mutect2, varscan2
- RALGAPA1 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.428); catalogued as COSV99354274; called by muse, mutect2, varscan2
- RPL34 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV67135666; called by muse, mutect2, varscan2
- TIGD6 | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV57060913; called by mutect2, varscan2
- TNFSF15 | c.493A>T p.I165F | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV65010207; called by muse, mutect2, varscan2
- UBE2R2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54289002; called by muse, mutect2
- HAUS4 | c.142_145del p.Q49Mfs*7 | Frame Shift Del (DEL) | VAF 33/166 reads (20%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3303del p.F1101Lfs*58 (on ENST00000296302 / NM_001366071.2; = p.F1076Lfs*58 on NM_018313.5) | Frame Shift Del (DEL) | VAF 94/239 reads (39%) | called by mutect2, pindel, varscan2
- TECTA | c.4716_4717dup p.F1573Yfs*3 | Frame Shift Ins (INS) | VAF 26/119 reads (22%) | called by mutect2, pindel, varscan2
- VHL | c.346_348del p.L116del | In Frame Del (DEL) | VAF 36/88 reads (41%) | called by mutect2, pindel, varscan2
- PEG3 | c.789C>T p.D263= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs142177720, COSV55627105; called by muse, mutect2, varscan2
- RIOK3 | c.186T>C p.A62= | Silent (SNP) | VAF 139/549 reads (25%) | catalogued as rs761333982, COSV59772916; called by muse, mutect2, varscan2
- SLC13A4 | c.1503G>A p.P501= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs781208193, COSV62460905; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663505 T>C | 3'Flank (SNP) | VAF 60/155 reads (39%) | called by muse, mutect2
- BTNL8 | c.787+44T>C | Intron (SNP) | VAF 57/252 reads (23%) | catalogued as COSV99180460; called by muse, mutect2, varscan2
- TMEM234 | c.387+27T>A | Intron (SNP) | VAF 26/82 reads (32%) | catalogued as COSV59084390; called by muse, mutect2, varscan2
